Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-6033, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-6033-01A (Primary Tumor).

Department of Pathology

Tissue Source Site (TSS) #: [REDACTED]

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL, (CLEAR CELLS 10%, EOSINOPHILIC CELLS 90%), FUHRMAN'S NUCLEAR GRADE 4. (SEE COMMENT)

TUMOR EXTENDS INTO THE PERINEPHRIC ADIPOSE TISSUE.

TUMOR MEASURES 13.5 CM IN MAXIMUM DIMENSION.

Vascular, ureteral and soft tissue margins of resection free of tumor.

COMMENT

The tumor focally exhibits marked anaplasia and increased mitotic activity; however, no sarcomatoid component is identified.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A nephrectomy specimen (16.0 x 14.5 x 9.0 cm) with attached ureter (13.0 cm in length and 0.5 cm in diameter). A rim of perinephric adipose tissue is present ranging in thickness from 0.5 to 2.5 cm.

A tumor (13.5 x 10.5 x 7.0 cm) is present occupying the majority of the kidney in the upper and mid portions. Only a 5.0 cm length of lower pole is uninvolved by the tumor. The tumor has lobulated edges, yellow-tan firm parenchyma. The peripheral areas of the tumor are gelatinous, gray-tan with areas of hemorrhage and cystic degeneration. The central areas of the tumor are firmer, with areas of hyalinization and degeneration. Irregular gelatinous viable areas are seen within the central portion of the tumor. The tumor is seen infiltrating into the perinephric adipose tissue; however, the Gerota's fascia is grossly free of the tumor. The tumor abuts the renal pelvis and the intra-pelvic adipose tissue. No tumor extension is seen in the renal vein. A satellite nodule 2.0 x 1.3 x 1.0 cm is seen in the upper part of lower pole. Representative material is taken for possible electron microscopy and for the tumor bank.

INK CODE: Blue - Gerota's fascia.

SECTION CODE: A1, ureteral and vascular resection margin; A2-A6, tumor infiltration in the perinephric fat; A7-A15, tumor; A16, tumor with adjacent unremarkable kidney; A17, A18, tumor abutting the renal pelvis; A19, tumor abutting intrapelvic fat; A20, tumor adjacent to the renal vein. [REDACTED]

CLINICAL HISTORY

Mass right renal.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 5d9bf9fd-72f1-4b12-bf0d-98281ef83793 (TCGA-CJ-6033.E48095F2-59EF-457A-B864-426FC9A0F118.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).